Somatic mutation profile of tumor specimen TCGA-19-0957-01C (aliquot TCGA-19-0957-01C-01W-0643-08) from TCGA case TCGA-19-0957, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 48.5 years (17,714 days).
Specimen TCGA-19-0957-01C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5081b73a-9827-4b0c-848c-873ae9bc6890.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-0957-10A (Blood Derived Normal), aliquot TCGA-19-0957-10A-01W-0643-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3b13f3b-c426-4c7b-874d-5f1508e9ddd9

The open-access MAF lists 91 somatic variants for this specimen: 67 protein-altering or splice-affecting, 24 silent.
By variant classification: Missense Mutation 51, Silent 24, Nonsense Mutation 8, Frame Shift Del 3, Splice Site 2, Frame Shift Ins 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.1026+1G>C p.X342_splice | Splice Site (SNP) | VAF 22/48 reads (46%) | hotspot (GDC flag); catalogued as rs786201041, CS043794, CS110216, COSV64288702, COSV64289135, COSV64293873; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RHO | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.809); catalogued as rs104893779, CM910342, CM930659, COSV99960759; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TRPV6 | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1281361203, COSV63892531; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABHD11 | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 10/211 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.342); catalogued as COSV99766635; called by muse, mutect2
- AC093525.2 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 34/149 reads (23%) | PolyPhen benign (0.003); catalogued as COSV53552173, COSV99566089; called by muse, mutect2, varscan2
- ACAD10 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as rs575221081, COSV58154089; called by muse, mutect2, varscan2
- ADA2 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 106/172 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs777683953, COSV52832469; called by muse, varscan2
- AGMO | c.1308G>T p.M436I | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100694613, COSV100694753; called by muse, mutect2
- AL121899.2 | c.1768C>T p.R590W | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs781217795, COSV101198618; called by muse, mutect2, varscan2
- AMPD3 | c.422C>T p.A141V (on ENST00000396553 / NM_001025389.2; = p.A150V on NM_000480.3) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV67333145; called by muse, mutect2, varscan2
- APOL1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 46/258 reads (18%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs1334345255, COSV100046306; called by muse, mutect2, varscan2
- ATP6V1A | c.398G>A p.W133* | Nonsense Mutation (SNP) | VAF 10/146 reads (7%) | catalogued as COSV99850332; called by muse, mutect2
- BPTF | c.4922C>T p.T1641M | Missense Mutation (SNP) | VAF 65/144 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as rs1017462944, COSV100073898; called by muse, mutect2, varscan2
- BTBD7 | c.2632G>T p.V878L | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.131); catalogued as COSV100598119; called by muse, mutect2
- C1orf122 | c.238-1G>T p.X80_splice | Splice Site (SNP) | VAF 6/56 reads (11%) | catalogued as COSV100888698; called by muse, varscan2
- CACNA1S | c.454A>G p.M152V | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.003); catalogued as rs369332959; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAPS2 | c.1510G>T p.G504* | Nonsense Mutation (SNP) | VAF 7/78 reads (9%) | catalogued as COSV100158120, COSV60824882; called by muse, mutect2
- CDH11 | c.1655G>A p.G552D | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as COSV99219496; called by muse, mutect2, varscan2
- CLCNKB | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100990435; called by muse, mutect2, varscan2
- COL12A1 | c.8888G>A p.G2963E | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59402994; called by muse, mutect2, varscan2
- COP1 | c.2167G>T p.G723C | Missense Mutation (SNP) | VAF 45/294 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99056663; called by muse, mutect2, varscan2
- CYP4A22 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 110/225 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.075); catalogued as rs536116490, COSV99595272; called by muse, mutect2, varscan2
- EHD4 | c.1585G>A p.V529M | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); catalogued as rs554166246, COSV99588267; called by muse, mutect2, varscan2
- FAM124A | c.790C>T p.R264C (on ENST00000322475 / NM_001242312.2; = p.R300C on NM_145019.4) | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54476071; called by muse, mutect2, varscan2
- FUBP1 | c.191A>G p.K64R | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99629441; called by muse, mutect2, varscan2
- GRIN2A | c.3728G>A p.G1243E | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1471308483, COSV100410743, COSV58020221; called by muse, mutect2
- IGSF9 | c.1546G>A p.V516M (on ENST00000368094 / NM_001135050.2; = p.V500M on NM_020789.4) | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs771632078, COSV63643036; called by muse, mutect2, varscan2
- KIN | c.458T>G p.L153R | Missense Mutation (SNP) | VAF 14/433 reads (3%) | SIFT tolerated (0.35); PolyPhen benign (0.057); catalogued as COSV101092669; called by muse, mutect2
- KIR3DL3 | c.1103G>T p.R368M | Missense Mutation (SNP) | VAF 57/434 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.16); catalogued as COSV52549480; called by muse, mutect2, varscan2
- LARS1 | c.2866C>T p.R956C (on ENST00000394434 / NM_020117.11; = p.R929C on NM_016460.3) | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as rs200546271; called by muse, mutect2, varscan2
- LEFTY1 | c.864C>A p.F288L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.498); catalogued as COSV99686601; called by muse, mutect2, varscan2
- LNPEP | c.2699C>A p.S900* | Nonsense Mutation (SNP) | VAF 10/154 reads (6%) | catalogued as COSV99183584; called by muse, mutect2
- MRPL4 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs372183483; called by muse, mutect2, varscan2
- MTARC2 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as COSV100831025; called by muse, mutect2, varscan2
- NCKAP1L | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 389/628 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs752125351, COSV53203384; called by muse, mutect2, varscan2
- NDST1 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.205); catalogued as rs1291890754, COSV55788566; called by muse, mutect2, varscan2
- NUP133 | c.2297C>T p.T766M | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as rs537234819, COSV54570575; called by muse, mutect2, varscan2
- OR8K1 | c.75C>A p.D25E | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); catalogued as rs769004561, COSV54401922; called by muse, mutect2, varscan2
- PDGFC | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 29/343 reads (8%) | catalogued as COSV56849803; called by muse, mutect2
- PDXDC1 | c.686T>C p.I229T | Missense Mutation (SNP) | VAF 24/322 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.16); catalogued as rs780031901, COSV100363382; called by muse, mutect2
- PGK2 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 145/372 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100505644; called by muse, mutect2, varscan2
- PIGM | c.496G>A p.V166I | Missense Mutation (SNP) | VAF 112/617 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs1261190161, COSV100928065; called by muse, mutect2, varscan2
- PIK3CG | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV100783093; called by muse, mutect2, varscan2
- PIP4K2C | c.236G>A p.S79N | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs774720885, COSV61606343, COSV61606568; called by muse, mutect2, varscan2
- PSMB2 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 15/233 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV100951608; called by muse, mutect2
- PTCH1 | c.3904C>T p.P1302S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs747093389, COSV100109660; called by muse, varscan2
- PTPRN2 | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as COSV101235229; called by muse, varscan2
- R3HDM1 | c.622G>T p.A208S | Missense Mutation (SNP) | VAF 7/202 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99926632; called by muse, mutect2
- RAB43 | c.365C>T p.S122F | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV100167622; called by muse, mutect2, varscan2
- RGS22 | c.538G>C p.A180P | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100693673; called by muse, mutect2, varscan2
- SEZ6L2 | c.727dup p.R243Pfs*75 (on ENST00000308713 / NM_001114099.3; = p.R173Pfs*75 on NM_012410.4) | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | catalogued as rs766468782; called by pindel, varscan2
- SH3PXD2B | c.1627C>G p.R543G | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.694); catalogued as COSV100288400; called by muse, mutect2, varscan2
- SLC2A3 | c.318C>A p.C106* | Nonsense Mutation (SNP) | VAF 19/142 reads (13%) | catalogued as COSV50005059, COSV99306435; called by muse, mutect2, varscan2
- TBX6 | c.849C>A p.D283E | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as COSV99661764; called by muse, mutect2, varscan2
- TCEAL5 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 136/428 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV101013171; called by muse, mutect2, varscan2
- THEMIS2 | c.1426C>T p.R476W | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100198123; called by muse, mutect2
- TLR7 | c.290G>A p.R97K | Missense Mutation (SNP) | VAF 89/769 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV101028085; called by muse, varscan2
- TMC2 | c.2028G>A p.M676I | Missense Mutation (SNP) | VAF 49/429 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62657742; called by muse, mutect2, varscan2
- TMEM132D | c.709G>T p.G237W | Missense Mutation (SNP) | VAF 49/86 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101399216; called by muse, mutect2, varscan2
- TNFSF11 | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 51/321 reads (16%) | catalogued as COSV99520656; called by muse, mutect2, varscan2
- WAPL | c.745G>T p.E249* | Nonsense Mutation (SNP) | VAF 27/134 reads (20%) | catalogued as COSV100077170; called by muse, mutect2, varscan2
- ZNF197 | c.485del p.A162Efs*12 | Frame Shift Del (DEL) | VAF 20/243 reads (8%) | catalogued as COSV60360591; called by mutect2, varscan2
- ZNF804B | c.1037G>T p.R346I | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.641); catalogued as COSV100305546; called by muse, mutect2, varscan2
- BRD3 | c.1175_1176insGGAGT p.P393Efs*20 | Frame Shift Ins (INS) | VAF 108/384 reads (28%) | called by pindel, varscan2
- MBD4 | c.625del p.S209Pfs*6 | Frame Shift Del (DEL) | VAF 16/169 reads (9%) | called by mutect2, varscan2
- RDM1 | c.88G>C p.A30P | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.855); called by mutect2, varscan2
- TNFRSF10A | c.537del p.C180Afs*63 | Frame Shift Del (DEL) | VAF 21/147 reads (14%) | called by mutect2, varscan2
- ABCA6 | c.2055C>A p.I685= | Silent (SNP) | VAF 72/383 reads (19%) | catalogued as COSV99447432; called by muse, mutect2, varscan2
- C4BPA | c.1761C>T p.S587= | Silent (SNP) | VAF 47/108 reads (44%) | catalogued as rs762923928, COSV100891174; called by muse, mutect2, varscan2
- FAM83B | c.2757G>A p.T919= | Silent (SNP) | VAF 62/190 reads (33%) | catalogued as rs746397400, COSV100174878; called by muse, mutect2, varscan2
- GRM1 | c.3390C>T p.D1130= | Silent (SNP) | VAF 46/182 reads (25%) | catalogued as COSV99268412; called by muse, mutect2, varscan2
- LILRA2 | c.852T>C p.P284= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as rs1281410212, COSV99253105; called by muse, mutect2, varscan2
- NAA11 | c.147C>T p.D49= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV54516092; called by muse, mutect2, varscan2
- NSMCE1 | c.555C>T p.P185= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs375663140; called by mutect2, varscan2
- NUP205 | c.3865C>T p.L1289= | Silent (SNP) | VAF 15/350 reads (4%) | catalogued as COSV99607418; called by muse, mutect2
- OR5AR1 | c.483C>A p.T161= | Silent (SNP) | VAF 167/464 reads (36%) | catalogued as COSV100265752; called by muse, mutect2, varscan2
- OR6C1 | c.868C>T p.L290= | Silent (SNP) | VAF 26/350 reads (7%) | catalogued as rs764123958, COSV101110545; called by muse, mutect2
- PASK | c.3270C>T p.L1090= | Silent (SNP) | VAF 38/86 reads (44%) | catalogued as COSV52152089; called by mutect2, varscan2
- PAX3 | c.1104C>T p.D368= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV100399928; called by muse, mutect2, varscan2
- POPDC3 | c.507C>T p.G169= | Silent (SNP) | VAF 47/97 reads (48%) | catalogued as rs774623615, COSV54644674; called by muse, mutect2, varscan2
- PRKAA2 | c.723C>T p.V241= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as rs753291156, COSV100983028; called by muse, mutect2, varscan2
- RALGAPA1 | c.870A>T p.A290= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV99355785; called by muse, mutect2, varscan2
- REV1 | c.669C>T p.A223= | Silent (SNP) | VAF 39/82 reads (48%) | catalogued as COSV99301345; called by muse, mutect2, varscan2
- RNF6 | c.1608C>A p.S536= | Silent (SNP) | VAF 9/201 reads (4%) | catalogued as COSV100644664; called by muse, mutect2
- SLC5A11 | c.645G>A p.A215= | Silent (SNP) | VAF 88/192 reads (46%) | catalogued as rs759987745, COSV61743396; called by muse, varscan2
- STYK1 | c.84C>T p.I28= | Silent (SNP) | VAF 40/178 reads (22%) | catalogued as rs769680668, COSV99312148; called by muse, mutect2, varscan2
- TLR7 | c.204G>A p.T68= | Silent (SNP) | VAF 79/775 reads (10%) | catalogued as rs199530355, COSV101028083; called by muse, varscan2
- USP25 | c.2976C>T p.Y992= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV99584372; called by muse, mutect2, varscan2
- ZHX1 | c.9C>T p.S3= | Silent (SNP) | VAF 46/354 reads (13%) | catalogued as COSV99933830; called by muse, mutect2, varscan2
- ZMAT4 | c.297C>T p.H99= | Silent (SNP) | VAF 354/634 reads (56%) | catalogued as rs189553545, COSV52708095, COSV52715861; called by muse, mutect2, varscan2
- ZNF318 | c.954G>A p.L318= | Silent (SNP) | VAF 90/376 reads (24%) | catalogued as COSV100546444; called by muse, mutect2, varscan2
